Somatic mutation profile of tumor specimen ALCH-B3ZK-TTP1-A (aliquot ALCH-B3ZK-TTP1-A-1-0-D-A80D-36) from ALCHEMIST case ALCH-B3ZK, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 62.0 years (22,636 days).
Specimen ALCH-B3ZK-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49ac62a8-0795-468d-82a4-def913423f60.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B3ZK-NB1-A (Blood Derived Normal), aliquot ALCH-B3ZK-NB1-A-1-0-D-A80D-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6dd34909-d03f-40f5-909c-7ec36b0c6bea

The open-access MAF lists 55 somatic variants for this specimen: 29 protein-altering or splice-affecting, 14 silent, 12 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 14, Intron 8, RNA 2, 5'UTR 2, Nonsense Mutation 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EGFR | c.2573T>G p.L858R | Missense Mutation (SNP) | VAF 219/670 reads (33%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121434568, COSV51765161, COSV51854030; ClinVar: likely pathogenic / drug response / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.374C>A p.T125K | Missense Mutation (SNP) | VAF 50/148 reads (34%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs786201057, CM102351, CM157948, COSV52667346, COSV52673504, COSV52688693, COSV99037266; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC068580.4 | c.518A>G p.K173R | Missense Mutation (SNP) | VAF 58/268 reads (22%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.039); catalogued as rs746140722; called by muse, mutect2, varscan2
- FRMPD4 | c.3403G>C p.D1135H | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.417); catalogued as COSV101044012; called by muse, mutect2, varscan2
- GLCCI1 | c.44C>T p.T15I | Missense Mutation (SNP) | VAF 20/156 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.934); catalogued as rs1490519816; called by muse, varscan2
- KPRP | c.743G>A p.R248H | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs193921023, COSV64222883; ClinVar: uncertain significance; called by muse, mutect2
- OR8K3 | c.412C>T p.R138* | Nonsense Mutation (SNP) | VAF 20/64 reads (31%) | catalogued as rs779168193; called by muse, mutect2, varscan2
- PCDHGB1 | c.1910G>A p.R637H | Missense Mutation (SNP) | VAF 34/436 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.549); catalogued as rs1446316732, COSV53982366; called by muse, mutect2
- PGK1 | c.1180A>G p.T394A | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as CM147134; called by muse, mutect2, varscan2
- RNMT | c.862C>T p.H288Y | Missense Mutation (SNP) | VAF 22/219 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100054672; called by muse, mutect2, varscan2
- YEATS2 | c.3771C>G p.I1257M | Missense Mutation (SNP) | VAF 20/166 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs371988576; called by muse, mutect2, varscan2
- ZNF486 | c.1193G>A p.R398K | Missense Mutation (SNP) | VAF 14/426 reads (3%) | SIFT tolerated (0.54); PolyPhen benign (0.007); catalogued as COSV58717317; called by muse, mutect2
- AADACL3 | c.904A>C p.K302Q | Missense Mutation (SNP) | VAF 13/276 reads (5%) | SIFT tolerated (0.58); PolyPhen benign (0.166); called by muse, mutect2
- AC011462.1 | c.1007_1009del p.D336del | In Frame Del (DEL) | VAF 46/312 reads (15%) | called by pindel, varscan2
- ADGRG4 | c.4961C>A p.P1654H | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.431); called by muse, mutect2
- AHDC1 | c.3995C>A p.A1332D | Missense Mutation (SNP) | VAF 47/306 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.399); called by muse, mutect2, varscan2
- ALOXE3 | c.1753T>A p.S585T | Missense Mutation (SNP) | VAF 128/418 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by muse, mutect2, varscan2
- CDK12 | c.2461A>C p.M821L | Missense Mutation (SNP) | VAF 22/196 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- COL6A3 | c.1369G>A p.G457R | Missense Mutation (SNP) | VAF 44/135 reads (33%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- CYLC1 | c.1606A>T p.T536S | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FHOD1 | c.2629C>G p.L877V | Missense Mutation (SNP) | VAF 68/271 reads (25%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- FREM1 | c.3557G>C p.S1186T | Missense Mutation (SNP) | VAF 36/258 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.02); called by mutect2, varscan2
- HEATR3 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 39/302 reads (13%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ITIH6 | c.2009T>A p.L670* | Nonsense Mutation (SNP) | VAF 59/171 reads (35%) | called by muse, mutect2, varscan2
- PLCH2 | c.4087C>A p.L1363M | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- RECQL4 | c.2647G>A p.E883K | Missense Mutation (SNP) | VAF 10/80 reads (13%) | SIFT tolerated (0.53); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- RELN | c.5627G>A p.R1876K | Missense Mutation (SNP) | VAF 12/364 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.915); called by muse, mutect2
- TOX4 | c.248A>G p.D83G | Missense Mutation (SNP) | VAF 47/268 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- USP32 | c.3126G>C p.M1042I | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.023); called by muse, mutect2
- AADAT | c.30G>A p.A10= | Silent (SNP) | VAF 29/219 reads (13%) | catalogued as rs755262373, COSV61787240; called by muse, mutect2, varscan2
- ADAL | c.759T>C p.H253= | Silent (SNP) | VAF 50/246 reads (20%) | called by muse, mutect2, varscan2
- BRDT | c.801T>C p.V267= | Silent (SNP) | VAF 8/176 reads (5%) | called by muse, mutect2
- CDX1 | c.201G>A p.A67= | Silent (SNP) | VAF 7/66 reads (11%) | called by muse, mutect2
- CEP350 | c.8160G>A p.L2720= | Silent (SNP) | VAF 12/234 reads (5%) | called by muse, mutect2
- CPS1 | c.1056T>G p.L352= | Silent (SNP) | VAF 18/210 reads (9%) | called by muse, mutect2
- GLIS1 | c.1743G>A p.A581= | Silent (SNP) | VAF 12/185 reads (6%) | catalogued as rs754330510; called by muse, mutect2
- LDHD | c.651C>T p.I217= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as rs763648113, COSV55581291; called by muse, mutect2
- MPV17 | c.339A>G p.G113= | Silent (SNP) | VAF 136/534 reads (25%) | called by muse, mutect2, varscan2
- PCDH7 | c.399G>T p.V133= | Silent (SNP) | VAF 22/96 reads (23%) | called by muse, mutect2, varscan2
- PCDHA8 | c.81G>A p.G27= | Silent (SNP) | VAF 47/257 reads (18%) | catalogued as rs782300357, COSV100970506; called by muse, mutect2, varscan2
- PERM1 | c.753A>G p.P251= | Silent (SNP) | VAF 77/342 reads (23%) | catalogued as rs1484640145; called by muse, mutect2, varscan2
- TAF1L | c.309A>C p.T103= | Silent (SNP) | VAF 28/226 reads (12%) | called by muse, mutect2, varscan2
- TBK1 | c.156A>G p.Q52= | Silent (SNP) | VAF 10/69 reads (14%) | catalogued as rs774600423; called by muse, mutect2, varscan2
- CALR3 | c.-5C>A | 5'UTR (SNP) | VAF 9/213 reads (4%) | called by muse, mutect2
- CMIP | c.478-6623G>A | Intron (SNP) | VAF 32/452 reads (7%) | catalogued as rs773847875; called by muse, mutect2
- COX6A1P2 | n.137C>T | RNA (SNP) | VAF 63/532 reads (12%) | catalogued as rs1173602724; called by muse, mutect2, varscan2
- CTAGE11P | n.101G>C | RNA (SNP) | VAF 44/740 reads (6%) | called by muse, mutect2
- FAM20A | c.405-2589A>G | Intron (SNP) | VAF 11/128 reads (9%) | called by muse, mutect2
- FKBP10 | c.1257-32G>A | Intron (SNP) | VAF 25/80 reads (31%) | called by muse, mutect2, varscan2
- FNTA | c.-15G>T | 5'UTR (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
- IRAG2 | c.3471+622G>A | Intron (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- MACF1 | c.220+18370G>C | Intron (SNP) | VAF 33/588 reads (6%) | called by muse, mutect2
- PNP | c.461+45A>G | Intron (SNP) | VAF 71/557 reads (13%) | called by muse, mutect2, varscan2
- SSUH2 | c.915+18G>T | Intron (SNP) | VAF 20/207 reads (10%) | called by muse, mutect2
- TGFB1 | c.1014+45del | Intron (DEL) | VAF 7/33 reads (21%) | called by mutect2, pindel, varscan2
